Somatic mutation profile of tumor specimen TCGA-ZF-AA4W-01A (aliquot TCGA-ZF-AA4W-01A-12D-A38G-08) from TCGA case TCGA-ZF-AA4W, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 56.4 years (20,611 days).
Specimen TCGA-ZF-AA4W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 525b354d-a5c0-43ac-a48b-c0883572c6c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA4W-10A (Blood Derived Normal), aliquot TCGA-ZF-AA4W-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34b78b06-feab-4a2e-a680-3ca67b7f3bcf

The open-access MAF lists 582 somatic variants for this specimen: 458 protein-altering or splice-affecting, 107 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 346, Silent 107, Frame Shift Del 55, Frame Shift Ins 26, Nonsense Mutation 23, Intron 6, RNA 5, Splice Site 4, Splice Region 3, 3'UTR 3, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as rs80356889, COSV100524854; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104894104, CM014526, CX073790, COSV58704067, COSV58704478, COSV58719419; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- JAG1 | c.693_694del p.R231Sfs*10 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | catalogued as rs876660978; ClinVar: pathogenic; called by pindel, varscan2
- KMT2D | c.9099del p.N3034Mfs*37 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs1064796855; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- PDHA1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555933954, COSV63328622; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs139261871; called by muse, mutect2, varscan2
- ABCA12 | c.4642G>A p.A1548T (on ENST00000272895 / NM_173076.3; = p.A1230T on NM_015657.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754893598, COSV55974837; called by muse, mutect2, varscan2
- ABCA13 | c.5621C>G p.S1874* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV70037022; called by muse, mutect2, varscan2
- ABHD8 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV53113345; called by muse, mutect2, varscan2
- AC253536.7 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99303827; called by muse, mutect2
- ACAD8 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752153225, COSV55542565; called by mutect2, varscan2
- ACAT1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as COSV54922226; called by muse, mutect2
- ADAM29 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63667993, COSV63669340; called by muse, mutect2
- ADAMTS15 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54509611; called by muse, mutect2
- ADAMTS16 | c.2172T>A p.N724K | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV56980125, COSV57006484; called by muse, mutect2, varscan2
- ADAMTS17 | c.1756A>G p.S586G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV51493221; called by muse, mutect2, varscan2
- ADGRB3 | c.4473G>T p.E1491D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV53259661; called by muse, mutect2, varscan2
- ADGRG1 | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV101113516; called by muse, mutect2
- ADGRV1 | c.16897G>A p.D5633N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV67994966; called by muse, mutect2, varscan2
- ADH1A | c.981A>T p.E327D | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52926151; called by muse, mutect2
- ADNP2 | c.2809C>T p.R937C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474057296, COSV51537414; called by muse, mutect2, varscan2
- AF196969.1 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as COSV52142279; called by muse, mutect2, varscan2
- AIFM2 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV104410916, COSV57160883; called by muse, mutect2, varscan2
- AKAP13 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as rs751149430, COSV63449521; called by muse, mutect2, varscan2
- AKAP13 | c.4633C>A p.P1545T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63363334; called by muse, varscan2
- AKNA | c.4081G>A p.A1361T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1356620382, COSV56340094; called by muse, mutect2, varscan2
- ALDH1B1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs746993033, COSV66619552; called by muse, mutect2, varscan2
- ALDH3B1 | c.951C>A p.A317= | Splice Region (SNP) | VAF 8/44 reads (18%) | catalogued as rs555223880, COSV99142030; called by muse, mutect2, varscan2
- ANKFY1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs62064367, COSV58916208; called by mutect2, varscan2
- ANKIB1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99729773; called by muse, mutect2, varscan2
- AP5Z1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV62243780; called by muse, mutect2, varscan2
- APC | c.5953G>A p.E1985K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as rs1561604028, COSV57380669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGAP2 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1393296120, COSV53570673; called by muse, mutect2
- ARFIP2 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99601623, COSV99601708; called by muse, mutect2, varscan2
- ARHGEF1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as rs183598386, COSV61526489; called by muse, mutect2, varscan2
- ARHGEF28 | c.3212del p.N1071Mfs*10 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs1221062011; called by mutect2, pindel, varscan2
- ARMC8 | c.665T>C p.V222A (on ENST00000469044 / NM_001363941.2; = p.V208A on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV61769530; called by muse, mutect2
- ASAH2 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61484381; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs747570359; called by mutect2, varscan2
- ASIC5 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs749340873, COSV73332967; called by muse, mutect2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs771531141; called by mutect2, varscan2
- ATP1A2 | c.2996A>G p.D999G | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV63403803, COSV63405772; called by muse, mutect2, varscan2
- BAZ2B | c.1687G>T p.G563W | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.715); catalogued as COSV58609671, COSV58611403; called by muse, mutect2, varscan2
- BBS9 | c.2269C>G p.L757V (on ENST00000242067 / NM_001348036.1; = p.L717V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.74); catalogued as COSV54167564, COSV54171808; called by muse, mutect2, varscan2
- BCR | c.889C>A p.L297M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV59935645; called by muse, mutect2
- BDP1 | c.7157G>A p.R2386H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs751700801, COSV62434568; called by muse, mutect2, varscan2
- BRINP2 | c.1726C>A p.L576I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV64178992; called by muse, mutect2
- BTAF1 | c.4850C>G p.S1617* | Nonsense Mutation (SNP) | VAF 15/114 reads (13%) | catalogued as COSV56429799, COSV56433860; called by muse, mutect2, varscan2
- C10orf120 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as COSV61492607; called by muse, mutect2, varscan2
- C1S | c.479del p.P160Rfs*9 | Frame Shift Del (DEL) | VAF 18/121 reads (15%) | catalogued as rs1555161771, COSV104410645; called by mutect2, pindel, varscan2
- C6orf118 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57812646, COSV57818950; called by muse, mutect2, varscan2
- CA5A | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59243197; called by muse, mutect2, varscan2
- CA6 | c.199A>G p.N67D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1186475199, COSV66262993; called by muse, mutect2, varscan2
- CACNA1E | c.3787C>G p.L1263V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100702061, COSV62419442; called by muse, mutect2, varscan2
- CACNA1G | c.5417G>A p.G1806D | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61738867; called by muse, mutect2, varscan2
- CACNG4 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50927840; called by muse, mutect2
- CAND1 | c.1066T>C p.C356R | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73338664; called by muse, mutect2, varscan2
- CD244 | c.803T>C p.L268S (on ENST00000368033 / NM_001166663.2; = p.L263S on NM_016382.4) | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as COSV59241485; called by muse, mutect2, varscan2
- CD33 | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV51804709; called by muse, mutect2, varscan2
- CDC5L | c.656dup p.P220Afs*7 | Frame Shift Ins (INS) | VAF 14/69 reads (20%) | catalogued as rs1446753250; called by mutect2, varscan2
- CDH26 | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV54845734, COSV54854486; called by muse, mutect2, varscan2
- CFAP92 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV54048870; called by muse, mutect2, varscan2
- CHAF1B | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV58441579; called by muse, mutect2, varscan2
- CHMP1B | c.347A>T p.D116V | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV52333766; called by muse, mutect2, varscan2
- CHRNA2 | c.449+1G>A p.X150_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV53559656; called by muse, mutect2, varscan2
- CLEC4E | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55225240, COSV55225875, COSV55227392; called by muse, mutect2, varscan2
- CLPTM1L | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV57992817; called by muse, mutect2, varscan2
- CLTC | c.4108G>A p.E1370K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52253004; called by muse, mutect2, varscan2
- CNTNAP1 | c.2240C>T p.T747I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV52854254; called by muse, mutect2, varscan2
- COBLL1 | c.1015C>T p.P339S (on ENST00000392717; = p.P301S on NM_014900.5) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.21); catalogued as COSV52076110; called by muse, mutect2, varscan2
- COL8A1 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.547); catalogued as rs778398809, COSV53742264; called by muse, mutect2, varscan2
- CPNE1 | c.847C>T p.Q283* (on ENST00000352393; = p.Q288* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 21/158 reads (13%) | catalogued as COSV100467971; called by muse, mutect2, varscan2
- CPZ | c.1295G>A p.R432K (on ENST00000360986 / NM_001014447.3; = p.R421K on NM_003652.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.843); catalogued as rs778856137, COSV59924254, COSV59926025; called by mutect2, varscan2
- CREB5 | c.1097G>A p.R366Q (on ENST00000357727 / NM_182898.4; = p.R359Q on NM_004904.3) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs376502932, COSV63228321; called by muse, mutect2, varscan2
- CSF2RA | c.4C>T p.L2F | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.088); catalogued as rs773708923, COSV62626689; called by muse, mutect2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- D2HGDH | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58323402; called by muse, mutect2, varscan2
- DAPK3 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV100009861; called by muse, mutect2
- DCAF15 | c.851dup p.E285* | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | catalogued as rs1363129995; called by mutect2, pindel, varscan2
- DDX43 | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.585); catalogued as rs748090175, COSV64837918; called by muse, mutect2, varscan2
- DDX60 | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV101190609, COSV67098851; called by muse, mutect2, varscan2
- DENND5B | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs199566202; called by muse, mutect2, varscan2
- DHCR7 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.147); catalogued as rs772162793, COSV62796659; called by muse, mutect2, varscan2
- DHRS9 | c.248A>T p.D83V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59141629; called by muse, mutect2, varscan2
- DHX9 | c.905A>G p.E302G | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV62362108; called by muse, mutect2
- DIP2A | c.3754G>C p.E1252Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV100595843, COSV59486614; called by muse, mutect2, varscan2
- DLC1 | c.4193A>G p.D1398G (on ENST00000276297 / NM_001348081.2; = p.D961G on NM_006094.5) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV52327071; called by muse, mutect2, varscan2
- DNAH8 | c.2278C>G p.L760V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV59478987; called by muse, mutect2, varscan2
- DNAI2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56762426; called by muse, mutect2
- DNAJC21 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.131); catalogued as rs766748592, COSV57762539; called by muse, mutect2, varscan2
- DNM1 | c.1993C>G p.L665V | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57855933; called by muse, mutect2
- DOCK1 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV54759438; called by muse, mutect2, varscan2
- DOP1A | c.1744C>A p.P582T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52715166, COSV52717850; called by muse, mutect2, varscan2
- DPY19L3 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV100639277; called by muse, mutect2
- DYRK3 | c.1400del p.G467Vfs*21 | Frame Shift Del (DEL) | VAF 32/206 reads (16%) | catalogued as rs781995280, COSV100895769; called by mutect2, pindel, varscan2
- DYSF | c.3223T>C p.F1075L | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV50571259; called by muse, mutect2, varscan2
- DYSF | c.4714G>A p.A1572T | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs143163327; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ECD | c.1443C>G p.I481M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV65901248; called by muse, mutect2, varscan2
- EDA | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV65784935; called by muse, mutect2, varscan2
- EDC4 | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs765594833, COSV59303842; called by mutect2, varscan2
- EEF2KMT | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs760548419, COSV69863075; called by muse, mutect2, varscan2
- EFR3A | c.1076del p.G359Dfs*3 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | catalogued as rs1563676977; called by mutect2, pindel, varscan2
- EFR3A | c.1375T>G p.S459A | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54462247; called by muse, mutect2, varscan2
- EHD1 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57736675; called by muse, mutect2, varscan2
- EHHADH | c.1657del p.R553Gfs*16 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as rs962197042, COSV51633732; called by mutect2, pindel, varscan2
- EIF4E3 | c.659G>T p.G220V (on ENST00000425534 / NM_001134651.2; = p.G114V on NM_173359.5) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV55206958; called by muse, mutect2, varscan2
- ELOA | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV69311329; called by muse, mutect2, varscan2
- EPS8 | c.1504T>A p.S502T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV55536364; called by muse, mutect2, varscan2
- ERCC6 | c.4325A>T p.D1442V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63394215; called by muse, mutect2, varscan2
- ESR1 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52802326; called by muse, mutect2, varscan2
- ESRP1 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100619358, COSV64412602; called by muse, mutect2, varscan2
- ETV3L | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs762918639, COSV71900983; called by muse, mutect2, varscan2
- FAM122A | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV55257434; called by muse, mutect2, varscan2
- FAM153A | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV62363563; called by muse, varscan2
- FAM83A | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99414524; called by muse, mutect2
- FAM83B | c.2759C>T p.S920F | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV60926634; called by muse, mutect2
- FAT1 | c.1499A>G p.Y500C | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766981976, COSV71674654; called by muse, mutect2
- FAT4 | c.9384C>A p.Y3128* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100629788; called by muse, mutect2, varscan2
- FBXL12 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56114929; called by muse, mutect2, varscan2
- FBXO47 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753916869, COSV65242812; called by muse, mutect2, varscan2
- FKBP10 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV58638948; called by muse, mutect2, varscan2
- FLG | c.9989G>C p.S3330T | Missense Mutation (SNP) | VAF 97/573 reads (17%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.928); catalogued as COSV64248718; called by muse, mutect2, varscan2
- FMNL1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138651184, COSV58956476; called by muse, mutect2, varscan2
- FNBP1 | c.1043C>G p.A348G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.08); catalogued as COSV100852767; called by muse, mutect2
- FOXA3 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100141439, COSV56217447; called by muse, mutect2
- FXN | c.337G>A p.A113T (on ENST00000377270; = p.A188T on NM_000144.5) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs776068810, COSV66010496; called by muse, mutect2, varscan2
- FYN | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.05); catalogued as COSV57620984; called by muse, mutect2, varscan2
- GABRB2 | c.1409G>A p.R470H (on ENST00000274547; = p.R432H on NM_000813.3) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1561596707, COSV50943765; called by muse, mutect2, varscan2
- GBP1 | c.963G>C p.Q321H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV65084490; called by muse, mutect2, varscan2
- GCNT3 | c.1056C>G p.Y352* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as rs563231408, COSV101251860; called by muse, mutect2, varscan2
- GIT2 | c.1703C>A p.S568Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.27); catalogued as rs773484065, COSV58085045; called by mutect2, varscan2
- GP2 | c.1511G>A p.G504D (on ENST00000381362 / NM_001007240.3; = p.G501D on NM_001502.4) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV56896573; called by muse, mutect2, varscan2
- GPR50 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54442672; called by muse, mutect2, varscan2
- GPR6 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV51571247, COSV51573087; called by muse, mutect2, varscan2
- GPRC5C | c.692del p.G231Afs*118 (on ENST00000652232; = p.G186Afs*118 on NM_018653.4) | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs1325128906; called by mutect2, pindel, varscan2
- GPRC6A | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | catalogued as COSV100114663; called by muse, mutect2, varscan2
- GPRIN1 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.15); catalogued as COSV56144968; called by muse, mutect2, varscan2
- GRIK2 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV59770918; called by muse, mutect2, varscan2
- GRK3 | c.1854del p.K618Nfs*7 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | catalogued as rs1371816265; called by mutect2, pindel, varscan2
- GRM4 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65219405; called by muse, mutect2, varscan2
- GSPT2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100468311; called by muse, mutect2
- GUCY1A1 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 37/349 reads (11%) | catalogued as rs749771282, COSV56650537; called by muse, mutect2, varscan2
- GYS1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs566356663, COSV54403571; called by muse, mutect2, varscan2
- GYS1 | c.660C>G p.F220L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV54405282; called by muse, mutect2, varscan2
- H3-3A | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as COSV64732350, COSV64734429; called by muse, mutect2, varscan2
- H4C3 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV58091381; called by muse, mutect2, varscan2
- HGS | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.586); catalogued as COSV61270247; called by muse, mutect2, varscan2
- HGS | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV61270254; called by muse, mutect2, varscan2
- HHIP | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV56838291; called by muse, mutect2
- HIPK1 | c.2581C>A p.L861M | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV61250581; called by muse, mutect2, varscan2
- HPR | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 5/102 reads (5%) | catalogued as COSV99930846; called by muse, mutect2
- HSP90AA1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53491281; called by muse, mutect2
- HSP90AA1 | c.1100G>C p.R367T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV53491300, COSV99070128; called by muse, mutect2, varscan2
- HSP90AA1 | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV53487833; called by muse, mutect2, varscan2
- HSPG2 | c.5011G>C p.E1671Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756266356, COSV65977094; called by muse, mutect2, varscan2
- IDO1 | c.447C>A p.D149E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV53716290; called by muse, varscan2
- IFT140 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs767571875, COSV68497716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMMT | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs555759519, COSV54490145; called by muse, mutect2, varscan2
- INTS13 | c.1489dup p.T497Nfs*7 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | catalogued as rs1363242314; called by mutect2, pindel, varscan2
- IQCH | c.1528dup p.I510Nfs*14 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | catalogued as rs776357245; called by mutect2, varscan2
- IRAG2 | c.3722A>T p.N1241I (on ENST00000636465; = p.N286I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63140812; called by muse, mutect2
- ITGB6 | c.1118C>G p.S373C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51798490; called by muse, mutect2, varscan2
- ITPK1 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.17); catalogued as rs757596570, COSV50900004; called by muse, mutect2
- ITPRIP | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV53393151; called by muse, mutect2, varscan2
- JAK1 | c.3289G>T p.G1097C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104397665, COSV53810789; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58027826; called by mutect2, varscan2
- KANK1 | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs149011172, COSV63214688; called by muse, mutect2, varscan2
- KANK4 | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58091947, COSV58094081; called by muse, mutect2, varscan2
- KANSL1 | c.3194G>A p.R1065H (on ENST00000574590 / NM_001193465.2; = p.R1066H on NM_015443.4) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs368475798, COSV52237183; called by muse, mutect2, varscan2
- KBTBD12 | c.1812G>A p.M604I | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59679343; called by muse, mutect2, varscan2
- KCNA3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901232; called by muse, mutect2, varscan2
- KEL | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100786828, COSV62337758; called by muse, mutect2, varscan2
- KIAA0825 | c.707A>T p.N236I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV56959753; called by muse, mutect2, varscan2
- KIAA0930 | c.876del p.T293Pfs*27 (on ENST00000336156 / NM_001009880.2; = p.T298Pfs*27 on NM_015264.2) | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs1294718664; called by mutect2, pindel, varscan2
- KIAA2026 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763070493, COSV67357680; called by muse, mutect2, varscan2
- KIDINS220 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56758898; called by muse, mutect2, varscan2
- KIF5B | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1270491359, COSV56654956, COSV56656236; called by muse, mutect2
- KIT | c.2160G>T p.E720D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.999); catalogued as COSV55392258; called by muse, mutect2, varscan2
- KLF17 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64857003; called by muse, mutect2, varscan2
- KRTAP10-5 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV59979273; called by muse, mutect2, varscan2
- LARP4B | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV60223908; called by muse, mutect2, varscan2
- LARS1 | c.1838del p.G613Vfs*18 (on ENST00000394434 / NM_020117.11; = p.G586Vfs*18 on NM_016460.3) | Frame Shift Del (DEL) | VAF 37/285 reads (13%) | catalogued as rs1448285386; called by mutect2, pindel, varscan2
- LCP2 | c.803C>G p.S268W | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.523); catalogued as rs201786815, COSV50464804; called by muse, mutect2, varscan2
- LDAH | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.013); catalogued as COSV52968420; called by muse, mutect2, varscan2
- LENG8 | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs768271224, COSV58730431; called by muse, mutect2, varscan2
- LHCGR | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.915); catalogued as COSV54302838; called by muse, mutect2, varscan2
- LIPF | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV53286250; called by muse, mutect2, varscan2
- LOXL2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427621921, COSV66693088; called by muse, mutect2, varscan2
- LPCAT3 | c.1436G>T p.R479M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54643882; called by muse, mutect2, varscan2
- LRFN3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318075884, COSV55817366; called by muse, mutect2, varscan2
- LRG1 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56706002; called by muse, mutect2
- LRRN2 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100912932, COSV65784271; called by muse, mutect2, varscan2
- LRRTM4 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV69142115; called by muse, mutect2
- MAP2 | c.989A>T p.K330M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52307338; called by muse, mutect2, varscan2
- MARK3 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53516001; called by muse, mutect2
- MATN2 | c.2675T>C p.L892S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV99646956; called by muse, mutect2, varscan2
- MCF2L2 | c.2974A>G p.T992A | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61061152; called by muse, mutect2
- MCM4 | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50632369; called by muse, mutect2, varscan2
- MCPH1 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs748320867, COSV60919166; called by muse, mutect2, varscan2
- MCTP2 | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV63291634, COSV63293134; called by muse, mutect2, varscan2
- MED23 | c.1747G>T p.G583* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100645335; called by muse, mutect2, varscan2
- MEIS2 | c.1169A>G p.D390G | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV54944507; called by muse, mutect2
- METTL4 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1426712682, COSV55249767; called by muse, mutect2
- MGA | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.622); catalogued as COSV54962716; called by muse, mutect2, varscan2
- MGAT5 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.576); catalogued as COSV56095898; called by muse, mutect2, varscan2
- MID1 | c.1798del p.H600Tfs*22 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as CD071368; called by mutect2, pindel, varscan2
- MKI67 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781387369, COSV64073963; called by muse, mutect2
- MMS22L | c.2546A>G p.Y849C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs1275484678, COSV51526394; called by muse, mutect2, varscan2
- MPP2 | c.1153G>A p.V385M (on ENST00000461854 / NM_001278372.2; = p.V361M on NM_005374.5) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762932371, COSV52233073, COSV52235482; called by muse, mutect2, varscan2
- MROH6 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV52788785; called by muse, mutect2, varscan2
- MTSS1 | c.895T>C p.Y299H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100275426; called by muse, mutect2
- MTURN | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV61023622, COSV61024464; called by muse, mutect2, varscan2
- MUC16 | c.37298T>C p.V12433A | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as rs1288493280, COSV67492068; called by muse, mutect2, varscan2
- MYH3 | c.3422C>T p.A1141V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1430754169, COSV56869815; called by muse, mutect2
- MYH7B | c.5809G>A p.A1937T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV52679432; called by muse, mutect2
- NAGK | c.403A>G p.N135D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV54904488; called by muse, mutect2, varscan2
- NAT10 | c.2004G>T p.Q668H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV57666181; called by muse, mutect2, varscan2
- NBEA | c.6247C>T p.R2083C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200761216, COSV59763814; called by muse, mutect2, varscan2
- NBEAL2 | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.309); catalogued as COSV99437275; called by muse, mutect2
- NBPF3 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59064310; called by muse, mutect2
- NCK2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51896232; called by muse, mutect2, varscan2
- NEB | c.13558C>T p.H4520Y | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV51458871; called by muse, mutect2, varscan2
- NEB | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV51458893; called by muse, varscan2
- NF2 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV58529855, COSV58530611; called by muse, mutect2, varscan2
- NHLRC4 | c.70T>A p.F24I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1474515981, COSV50321146; called by muse, mutect2, varscan2
- NKAPL | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV59199251; called by muse, mutect2, varscan2
- NOMO1 | c.2903C>G p.S968C | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99814814; called by muse, mutect2, varscan2
- NOP58 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51898564; called by muse, mutect2, varscan2
- NOTCH3 | c.2501G>A p.S834N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.197); catalogued as COSV54649261; called by muse, mutect2, varscan2
- NPAP1 | c.2157G>T p.K719N | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV61510886; called by muse, mutect2, varscan2
- NPC1L1 | c.1262G>T p.R421M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56930117; called by muse, mutect2, varscan2
- NPHP1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV57211451; called by muse, mutect2, varscan2
- NR4A1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242149608, COSV54485593; called by muse, mutect2, varscan2
- NRIP1 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV59660226; called by muse, mutect2, varscan2
- NSD1 | c.7897C>T p.R2633W | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs758475990, COSV61782919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUFIP2 | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56605902; called by muse, mutect2, varscan2
- OAZ3 | c.434T>C p.F145S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100162656; called by muse, mutect2
- ONECUT2 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1449358331, COSV72153018; called by muse, mutect2, varscan2
- OR10A6 | c.890T>C p.M297T | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV59166082; called by muse, mutect2, varscan2
- OR5K4 | c.237del p.K80Rfs*3 | Frame Shift Del (DEL) | VAF 77/361 reads (21%) | catalogued as COSV61583533; called by mutect2, pindel, varscan2
- OR6Q1 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1289683950, COSV56934619; called by muse, mutect2, varscan2
- OR8J3 | c.871A>C p.S291R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56884191; called by muse, varscan2
- OXNAD1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53268980; called by muse, mutect2, varscan2
- OXR1 | c.1198G>C p.E400Q (on ENST00000442977 / NM_001198532.1; = p.E399Q on NM_018002.3) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.113); catalogued as COSV56336026; called by muse, mutect2, varscan2
- PAQR4 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142699591; called by muse, mutect2, varscan2
- PATL1 | c.478dup p.Q160Pfs*6 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs757903860; called by mutect2, varscan2
- PBRM1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as COSV56262392, COSV99970445; called by muse, mutect2
- PCDH10 | c.2979G>T p.Q993H | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV52103590; called by muse, mutect2, varscan2
- PCDHA6 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1481552888, COSV65342059; called by muse, varscan2
- PCDHB12 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554286888, COSV53392914; called by muse, mutect2, varscan2
- PDE10A | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1327070657, COSV63105916; called by muse, mutect2, varscan2
- PDE3B | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56390445; called by muse, mutect2, varscan2
- PDE6C | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.048); catalogued as rs557957487, COSV65115070, COSV65117644; called by mutect2, varscan2
- PDPR | c.2330C>G p.S777* | Nonsense Mutation (SNP) | VAF 73/200 reads (37%) | catalogued as COSV99848755; called by muse, mutect2, varscan2
- PI16 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.092); catalogued as COSV65448659; called by muse, mutect2, varscan2
- PIAS3 | c.1804dup p.A602Gfs*42 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | catalogued as rs782068335; called by mutect2, varscan2
- PLCB4 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs781223972, COSV53794363, COSV53810880; called by muse, mutect2, varscan2
- PLCG1 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54823815; called by muse, mutect2, varscan2
- PLEKHH2 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); catalogued as rs758831085, COSV56760156; called by muse, mutect2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs765091847; called by mutect2, varscan2
- PLPPR1 | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66457652; called by muse, mutect2
- PMPCA | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV65511011; called by muse, mutect2, varscan2
- PNN | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as rs546480407, COSV53766424; called by muse, mutect2
- POLD1 | c.2145G>T p.E715D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV70957199; called by muse, mutect2, varscan2
- PPP1R10 | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.006); catalogued as rs761017174, COSV64738709; called by muse, mutect2, varscan2
- PPP1R18 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV51298684; called by muse, mutect2, varscan2
- PPP1R3A | c.2954C>G p.S985* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV99492901, COSV99493950; called by muse, mutect2, varscan2
- PPP1R3C | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53287928, COSV53288505; called by muse, mutect2, varscan2
- PPRC1 | c.4382del p.P1461Hfs*79 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | catalogued as COSV53386648; called by pindel, varscan2
- PPWD1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54335588; called by muse, mutect2, varscan2
- PRAM1 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV55317028; called by muse, varscan2
- PREPL | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV53219280; called by muse, mutect2, varscan2
- PSMB7 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.276); catalogued as COSV52332700; called by muse, mutect2, varscan2
- PTCH2 | c.2605del p.L869Wfs*124 | Frame Shift Del (DEL) | VAF 28/219 reads (13%) | catalogued as COSV64711470; called by mutect2, pindel, varscan2
- RABEP2 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs746171043, COSV62869266; called by muse, mutect2, varscan2
- RAD17 | c.806G>T p.R269M (on ENST00000380774 / NM_133339.2; = p.R258M on NM_002873.1) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51459565; called by muse, mutect2, varscan2
- RAG1 | c.2481G>T p.E827D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1304782664, COSV55028054, COSV55028152; called by muse, mutect2, varscan2
- RAPH1 | c.3499G>A p.A1167T | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV55589330; called by muse, mutect2
- RBMXL2 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs779585410, COSV60981650; called by muse, mutect2, varscan2
- RBP5 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV56940145; called by muse, mutect2, varscan2
- RCBTB2 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV60650108; called by muse, mutect2, varscan2
- RERE | c.3304G>C p.E1102Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1426597394, COSV61953577; called by muse, mutect2, varscan2
- REV3L | c.1910C>G p.S637* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100725603; called by muse, mutect2, varscan2
- RHBDL3 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746464304, COSV52186467; called by muse, mutect2, varscan2
- RHOB | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55357246; called by muse, mutect2, varscan2
- RMDN1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as COSV52210539; called by muse, mutect2, varscan2
- RMI2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV56964465; called by muse, mutect2
- RNF2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1257220188, COSV62280511; called by muse, mutect2, varscan2
- RNF216 | c.873G>T p.T291= (on ENST00000425013 / NM_207116.3; = p.T348= on NM_207111.4) | Splice Region (SNP) | VAF 12/81 reads (15%) | catalogued as rs754494362, COSV66292647; called by muse, mutect2, varscan2
- ROS1 | c.4999C>T p.P1667S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV63861525; called by muse, mutect2, varscan2
- RSRC2 | c.765G>C p.K255N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV59207019; called by muse, mutect2, varscan2
- RXRA | c.331del p.L111Wfs*57 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as COSV62684236; called by mutect2, pindel, varscan2
- S100A7 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV64193227; called by muse, mutect2, varscan2
- SARS2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as COSV55501634; called by muse, mutect2, varscan2
- SCG2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59541774; called by muse, mutect2, varscan2
- SCGB1D1 | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60377322, COSV60378016; called by muse, mutect2, varscan2
- SDHB | c.752G>T p.R251M | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV64965163, COSV64965738; called by muse, mutect2, varscan2
- SEC16B | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251613455, COSV57628043; called by muse, mutect2, varscan2
- SERAC1 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as COSV65597965; called by muse, mutect2, varscan2
- SERPINE1 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV56171425; called by muse, mutect2
- SHCBP1 | c.1583A>G p.K528R | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV57650258; called by muse, mutect2, varscan2
- SHKBP1 | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99399318; called by muse, mutect2, varscan2
- SKIL | c.1771C>G p.Q591E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1208149753, COSV52062973; called by muse, mutect2, varscan2
- SLC25A12 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 24/128 reads (19%) | catalogued as COSV99785349; called by muse, mutect2, varscan2
- SLC25A41 | c.100del p.Q34Nfs*44 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs745556777; called by mutect2, pindel, varscan2
- SLC26A4 | c.2335G>C p.A779P | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); catalogued as rs776447767, COSV55919989; called by muse, mutect2, varscan2
- SLC4A10 | c.3106G>C p.D1036H (on ENST00000446997 / NM_001354461.2; = p.D1006H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55798987; called by muse, mutect2, varscan2
- SLC52A3 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as rs1349560607, COSV54079252; called by muse, mutect2
- SLC7A9 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV50082955, COSV50093680; called by muse, mutect2, varscan2
- SLIT2 | c.2246C>G p.P749R | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56594584; called by muse, mutect2, varscan2
- SMARCA1 | c.2036C>G p.S679C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100946527; called by muse, mutect2
- SMC1B | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as COSV100663449; called by muse, mutect2
- SMC2 | c.2360G>A p.R787K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.812); catalogued as COSV53964415; called by muse, mutect2, varscan2
- SMPD1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV54970629; called by muse, mutect2, varscan2
- SNX32 | c.1120C>T p.L374F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57450584; called by muse, mutect2, varscan2
- SP8 | c.1088G>A p.C363Y (on ENST00000361443 / NM_198956.4; = p.C381Y on NM_182700.6) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63866947; called by muse, mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs750890082; called by mutect2, varscan2
- SPIDR | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374317684; called by mutect2, varscan2
- SSRP1 | c.1865C>A p.S622Y | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV53481552; called by muse, mutect2, varscan2
- SSTR1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1566438902, COSV57457072, COSV57457940; called by mutect2, varscan2
- ST6GALNAC3 | c.827del p.G276Vfs*20 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as COSV60336092; called by mutect2, pindel
- SUSD5 | c.718T>C p.S240P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58880589; called by muse, mutect2, varscan2
- SYNGR2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs140124425; called by muse, mutect2, varscan2
- SYNGR4 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as rs1305494148, COSV61226018; called by muse, mutect2, varscan2
- TAAR9 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV71512335; called by muse, mutect2, varscan2
- TAF5 | c.1122dup p.G375Wfs*9 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | catalogued as rs1467943977; called by mutect2, pindel, varscan2
- TAOK2 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1256067563, COSV54239663, COSV54240749; called by muse, mutect2, varscan2
- TAS1R2 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143077243; called by muse, mutect2, varscan2
- TBC1D10B | c.1797G>C p.E599D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV99977194; called by muse, mutect2
- TBC1D15 | c.253C>G p.H85D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV59852872; called by muse, mutect2, varscan2
- TBX5 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557183241, COSV59862979; called by muse, mutect2, varscan2
- TCL1A | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV68086187; called by muse, mutect2, varscan2
- TEKT3 | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV58629801; called by muse, mutect2, varscan2
- TESK2 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.642); catalogued as rs754978881, COSV59149445; called by muse, mutect2, varscan2
- TFAP2C | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs773514336, COSV52373135; called by muse, mutect2, varscan2
- TFEB | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs148691652; called by muse, mutect2, varscan2
- TGFBR2 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV55447425, COSV99846750; called by muse, mutect2, varscan2
- TGIF2LX | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs754800415, COSV52214023; called by mutect2, varscan2
- THRAP3 | c.2269dup p.T757Nfs*6 | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | catalogued as rs1443424346; called by mutect2, pindel, varscan2
- THYN1 | c.481-1G>A p.X161_splice | Splice Site (SNP) | VAF 21/99 reads (21%) | catalogued as COSV55542553; called by muse, mutect2, varscan2
- TIMD4 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV50860073; called by muse, mutect2, varscan2
- TJP2 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs749225630, COSV55273947; called by muse, mutect2, varscan2
- TLK2 | c.1511A>G p.K504R (on ENST00000326270 / NM_001284333.2; = p.K482R on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58308100; called by muse, mutect2
- TLN2 | c.3683A>G p.D1228G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as COSV60895538; called by muse, mutect2, varscan2
- TLR3 | c.1259C>G p.S420* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV99711155; called by muse, mutect2, varscan2
- TLX2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV99283751; called by muse, mutect2
- TMEM106A | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57835450; called by muse, mutect2, varscan2
- TMEM119 | c.281A>T p.Y94F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV67189361; called by muse, mutect2, varscan2
- TMEM219 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV54244730; called by muse, mutect2, varscan2
- TNFAIP3 | c.1777C>G p.Q593E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV52796389, COSV52802126; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1239176693, COSV64423597; called by muse, mutect2, varscan2
- TNS3 | c.2036G>A p.G679D | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1250342093, COSV60799045; called by muse, mutect2, varscan2
- TP53 | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52675628, COSV53153773, COSV53585006; called by muse, mutect2, varscan2
- TPX2 | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV55922816; called by muse, mutect2, varscan2
- TRAK2 | c.811T>G p.S271A | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV60274950; called by muse, mutect2, varscan2
- TRAPPC11 | c.2986C>A p.P996T | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV58219162; called by muse, mutect2
- TRAV38-1 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs1006841158; called by muse, mutect2, varscan2
- TRDN | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV62113978; called by muse, mutect2
- TRPM2 | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.25); catalogued as COSV55976558; called by muse, mutect2, varscan2
- TRPM3 | c.1745G>A p.G582E (on ENST00000357533 / NM_001366142.2; = p.G415E on NM_020952.6) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV62594462; called by muse, mutect2, varscan2
- TTBK2 | c.2627del p.N876Ifs*10 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs1373884363; called by pindel, varscan2
- TTC8 | c.260C>A p.P87H (on ENST00000338104 / NM_001288781.1; = p.P97H on NM_144596.4) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV57630524; called by muse, mutect2
- TTN | c.93920A>G p.N31307S (on ENST00000591111; = p.N23883S on NM_003319.4) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | PolyPhen probably damaging (0.994); catalogued as COSV60335214; called by muse, mutect2, varscan2
- TTN | c.66542A>G p.Y22181C (on ENST00000591111; = p.Y14757C on NM_003319.4) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | PolyPhen probably damaging (0.939); catalogued as COSV60335265; called by muse, mutect2, varscan2
- TULP4 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757109055, COSV65578409; called by muse, mutect2, varscan2
- TUT4 | c.4868-1G>A p.X1623_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV57119681; called by muse, mutect2, varscan2
- U2SURP | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763880358, COSV67533181; called by muse, mutect2, varscan2
- UBLCP1 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57144809; called by muse, mutect2, varscan2
- UBR4 | c.11731G>C p.D3911H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV64398964; called by muse, mutect2, varscan2
- UCKL1 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV62403770; called by muse, mutect2, varscan2
- UGGT1 | c.1961T>C p.I654T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV52141355; called by muse, mutect2, varscan2
- UGT2B17 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as rs1472148067, COSV58502605; called by muse, mutect2, varscan2
- UHRF1 | c.1719T>G p.F573L (on ENST00000612630 / NM_001290050.1; = p.F586L on NM_013282.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV53576716; called by muse, mutect2, varscan2
- UNC5C | c.1836C>G p.C612W | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV71662118; called by muse, mutect2, varscan2
- UNC93B1 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57097599, COSV57100172, COSV57100967; called by muse, mutect2, varscan2
- USH2A | c.9224G>C p.R3075T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.115); catalogued as rs770809696, COSV56432970; called by muse, mutect2, varscan2
- USP37 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1185673671, COSV51447200, COSV99294029; called by muse, mutect2, varscan2
- UTP4 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1030203914, COSV58734562; called by muse, mutect2
- VEZT | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99704217; called by muse, mutect2
- VMP1 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV51867069, COSV51872364; called by muse, mutect2, varscan2
- VPS13C | c.1457del p.K486Rfs*6 (on ENST00000644861 / NM_020821.3; = p.K443Rfs*6 on NM_017684.5) | Frame Shift Del (DEL) | VAF 29/187 reads (16%) | catalogued as rs1485323338, COSV51120106; called by mutect2, pindel, varscan2
- VPS37A | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs755402438, COSV61365503; called by muse, mutect2, varscan2
- VPS39 | c.896G>T p.S299I (on ENST00000348544 / NM_001301138.2; = p.S288I on NM_015289.5) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV58793182; called by muse, mutect2, varscan2
- WDR35 | c.3041C>G p.S1014C (on ENST00000345530 / NM_001006657.2; = p.S1003C on NM_020779.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV55600954, COSV55606785; called by muse, mutect2, varscan2
- WDR81 | c.4411G>A p.A1471T (on ENST00000409644 / NM_001163809.2; = p.A420T on NM_152348.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769333879, COSV58478327; called by muse, mutect2, varscan2
- XIRP2 | c.68G>A p.G23E (on ENST00000628543; = p.G198E on NM_152381.6) | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV54732943; called by muse, mutect2, varscan2
- XRCC5 | c.858del p.E287Kfs*11 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs1559240395; called by mutect2, pindel, varscan2
- ZC3HAV1 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV54300751; called by muse, mutect2, varscan2
- ZDBF2 | c.3031G>A p.V1011I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV65629839; called by muse, mutect2, varscan2
- ZFP14 | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54204679; called by muse, mutect2, varscan2
- ZGRF1 | c.4009G>C p.E1337Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV58411329; called by muse, mutect2
- ZMYM4 | c.3877G>C p.E1293Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV58917002; called by muse, mutect2
- ZNF160 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV62000775; called by muse, mutect2, varscan2
- ZNF200 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV67723599; called by muse, mutect2, varscan2
- ZNF224 | c.1641G>C p.K547N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61241726, COSV61243427; called by muse, mutect2, varscan2
- ZNF236 | c.4167+1G>A p.X1389_splice | Splice Site (SNP) | VAF 14/95 reads (15%) | catalogued as COSV53497430; called by muse, mutect2, varscan2
- ZNF25 | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV56924114; called by muse, mutect2, varscan2
- ZNF518B | c.748A>T p.T250S | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58724798; called by muse, mutect2
- ZNF567 | c.1411C>T p.H471Y (on ENST00000536254 / NM_001322913.1; = p.H440Y on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62446476; called by muse, mutect2, varscan2
- ZNF600 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV100592879, COSV57745109; called by muse, mutect2
- ZNF609 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58589846; called by muse, mutect2
- ZNF611 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV60543295; called by muse, mutect2
- ZNF699 | c.1788C>G p.F596L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs372272252; called by muse, mutect2, varscan2
- ZNF808 | c.2238G>C p.Q746H | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.697); catalogued as COSV63119118, COSV63121656; called by muse, mutect2, varscan2
- ZNF816 | c.1226G>C p.R409T | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV54410909, COSV54412235, COSV54412463; called by muse, mutect2
- ZNF829 | c.1166T>C p.F389S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66986948; called by muse, mutect2, varscan2
- AARS2 | c.1709del p.G570Afs*21 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- ACACA | c.5212A>G p.R1738G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- ACSL4 | c.1821-3del | Splice Region (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel
- ACTL7B | c.164dup p.D55Efs*47 | Frame Shift Ins (INS) | VAF 15/117 reads (13%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.1341dup p.T448Yfs*7 | Frame Shift Ins (INS) | VAF 17/98 reads (17%) | called by mutect2, pindel, varscan2
- ANKRD13A | c.346del p.I116Ffs*11 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- ATP6V1H | c.736dup p.S246Ffs*13 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- BIRC6 | c.13896del p.P4633Lfs*11 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- BLNK | c.950del p.G317Efs*69 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- CCDC116 | c.1099dup p.R367Pfs*25 | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- CCDC18 | c.1905dup p.A636Sfs*10 (on ENST00000343253 / NM_001306076.1; = p.A637Sfs*10 on NM_206886.4) | Frame Shift Ins (INS) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- CCDC80 | c.2294del p.K765Sfs*19 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel, varscan2
- CHD1 | c.3960dup p.E1321Rfs*17 | Frame Shift Ins (INS) | VAF 14/101 reads (14%) | called by mutect2, varscan2
- COL2A1 | c.3641dup p.G1215Wfs*38 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by pindel, varscan2
- CUL4B | c.2193_2194del p.L732Kfs*5 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by pindel, varscan2
- DHX29 | c.369del p.K123Nfs*23 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- FANCI | c.3578del p.N1193Ifs*6 (on ENST00000310775 / NM_001376911.1; = p.N1133Ifs*6 on NM_018193.3) | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- FNIP2 | c.2212del p.M738Wfs*5 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- HP1BP3 | c.394del p.T132Qfs*13 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel
- HSPG2 | c.6848del p.G2283Afs*43 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- IPO11 | c.716dup p.L239Ffs*6 | Frame Shift Ins (INS) | VAF 10/108 reads (9%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 23/124 reads (19%) | called by mutect2, varscan2
- LRGUK | c.1975del p.T659Hfs*19 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- MACROD2 | c.1321dup p.A441Gfs*4 (on ENST00000642719; = p.A413Gfs*4 on NM_080676.6 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- MAP1A | c.7499del p.P2500Lfs*93 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel, varscan2
- MDC1 | c.4995del p.T1666Qfs*10 | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | called by mutect2, pindel, varscan2
- MIA3 | c.2237dup p.N746Kfs*10 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | called by mutect2, varscan2
- MSH6 | c.1087_1089del p.T363del | In Frame Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel, varscan2
- NHLRC1 | c.372del p.T125Pfs*107 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, varscan2
- NRM | c.187dup p.L63Pfs*21 | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- OR51Q1 | c.677dup p.N226Kfs*10 | Frame Shift Ins (INS) | VAF 19/108 reads (18%) | called by mutect2, pindel, varscan2
- P2RY12 | c.111dup p.V38Cfs*19 | Frame Shift Ins (INS) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- PARP1 | c.708del p.A237Pfs*2 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- PCDHB10 | c.2228dup p.A744Rfs*2 | Frame Shift Ins (INS) | VAF 16/148 reads (11%) | called by mutect2, pindel, varscan2
- PDS5A | c.2274del p.F758Lfs*8 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- PHF3 | c.1453del p.S485Vfs*2 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- PLCB1 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); called by muse, mutect2
- PLXNA2 | c.92del p.P31Qfs*23 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- RNF220 | c.269dup p.S91Ffs*25 | Frame Shift Ins (INS) | VAF 44/297 reads (15%) | called by mutect2, pindel, varscan2
- SGK2 | c.206del p.P69Qfs*55 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- SIPA1 | c.189del p.T64Rfs*112 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- SMIM15 | c.180del p.K60Nfs*12 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- SMYD3 | c.531dup p.V178Sfs*10 (on ENST00000490107 / NM_001375962.1; = p.V119Sfs*10 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- SORL1 | c.5418dup p.V1807Sfs*11 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- SPIC | c.437dup p.N146Kfs*50 | Frame Shift Ins (INS) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- USP20 | c.2520del p.I843Lfs*17 | Frame Shift Del (DEL) | VAF 11/107 reads (10%) | called by mutect2, pindel, varscan2
- USP37 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 7/190 reads (4%) | called by muse, mutect2
- ZNF616 | c.2191del p.S731Pfs*35 | Frame Shift Del (DEL) | VAF 19/131 reads (15%) | called by mutect2, pindel, varscan2
- ZSWIM4 | c.2948del p.L983Wfs*31 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- ABCB8 | c.408C>A p.L136= (on ENST00000297504 / NM_001282291.2; = p.L119= on NM_007188.5) | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV52510102; called by muse, mutect2, varscan2
- ACSL1 | c.936A>G p.P312= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs371855405, COSV55666427; called by muse, mutect2, varscan2
- ACTG1 | c.837C>T p.F279= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as rs77274428; called by muse, mutect2, varscan2
- AHCYL2 | c.492T>C p.D164= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs1307019609, COSV61491064; called by muse, varscan2
- AMFR | c.435G>A p.V145= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV51924241; called by muse, mutect2, varscan2
- ANPEP | c.2715G>C p.V905= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV55594815; called by muse, mutect2, varscan2
- AREL1 | c.2451C>T p.C817= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as rs369161965; called by muse, mutect2, varscan2
- ARMCX2 | c.645C>A p.T215= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV57531104, COSV57531179; called by muse, mutect2, varscan2
- ATL1 | c.1507C>T p.L503= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV63297684; called by muse, mutect2, varscan2
- BMPER | c.1977C>T p.C659= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as rs766776338, COSV51830988; called by muse, mutect2, varscan2
- BMS1 | c.1590C>T p.C530= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV65734756; called by muse, mutect2, varscan2
- BRD3 | c.93G>A p.K31= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1358769749, COSV57706542; called by muse, mutect2, varscan2
- BRWD3 | c.2310T>G p.S770= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV64753513; called by muse, mutect2, varscan2
- CASP3 | c.681C>A p.A227= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV57725842; called by muse, mutect2, varscan2
- CASZ1 | c.4416G>A p.T1472= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1259907593, COSV65460963; called by muse, mutect2, varscan2
- CCDC40 | c.3198G>T p.V1066= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV56412067; called by muse, mutect2, varscan2
- CCDC80 | c.2475T>C p.V825= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV52819779; called by muse, mutect2, varscan2
- CEMIP2 | c.42C>G p.L14= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV65489470; called by muse, mutect2, varscan2
- CLPP | c.231G>A p.S77= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1344090603, COSV55537341; called by muse, mutect2, varscan2
- COBL | c.1153C>T p.L385= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV54357843; called by muse, mutect2, varscan2
- COL8A2 | c.2064G>A p.T688= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs374239481; called by muse, mutect2, varscan2
- CPNE1 | c.783C>T p.I261= (on ENST00000352393; = p.I266= on NM_003915.5) | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs780991940, COSV58294915; called by muse, mutect2, varscan2
- CRAMP1 | c.807G>C p.L269= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV53530767; called by muse, mutect2, varscan2
- DLG2 | c.1584C>T p.S528= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs138430783, COSV54683626, COSV54687593; called by muse, mutect2, varscan2
- DND1 | c.519C>T p.S173= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100298229; called by muse, mutect2
- ELP2 | c.2397A>C p.A799= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV60854347; called by muse, mutect2, varscan2
- EPPK1 | c.5997G>A p.E1999= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1020981879, COSV73262356; called by muse, mutect2, varscan2
- F8 | c.4578T>C p.P1526= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV64278456; called by muse, mutect2, varscan2
- FABP12 | c.318G>A p.T106= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs368067152; called by muse, mutect2, varscan2
- FAM171B | c.1735C>A p.R579= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV59003584, COSV59008479; called by muse, mutect2, varscan2
- FAT3 | c.10956C>A p.R3652= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV53171658; called by muse, mutect2
- FBH1 | c.891A>G p.T297= (on ENST00000362091 / NM_178150.3; = p.T348= on NM_032807.4) | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1448187707, COSV62984428; called by muse, mutect2, varscan2
- GALNT3 | c.546T>C p.P182= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV67062485; called by muse, mutect2, varscan2
- GNAS | c.885T>C p.D295= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV55687246; called by muse, mutect2, varscan2
- GNPTG | c.201C>G p.L67= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV50189947; called by muse, mutect2
- HCRTR2 | c.1278C>G p.L426= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100904649, COSV63795806; called by muse, mutect2
- HIPK4 | c.474C>T p.D158= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV52524878, COSV52525459; called by muse, mutect2, varscan2
- HSD11B1 | c.597G>A p.K199= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV54827095, COSV54829694; called by muse, mutect2
- IFT122 | c.405C>T p.I135= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV56207950; called by muse, mutect2
- IGHV1-18 | c.255C>T p.G85= | Silent (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- IGSF3 | c.3366C>T p.N1122= (on ENST00000369486 / NM_001007237.3; = p.N1142= on NM_001542.4) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs772869930, COSV59589274; called by muse, mutect2, varscan2
- IP6K3 | c.483C>A p.T161= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs749410294, COSV53391777; called by muse, mutect2, varscan2
- KANK1 | c.1983C>T p.A661= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs763629960, COSV63211105; called by muse, mutect2
- L3MBTL1 | c.2133C>T p.R711= (on ENST00000418998 / NM_001377303.1; = p.R621= on NM_015478.7) | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs751448981, COSV64229621; called by muse, mutect2, varscan2
- LAMA1 | c.7005C>A p.T2335= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV67544140; called by muse, mutect2, varscan2
- LRBA | c.1350C>G p.L450= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV63964514; called by muse, mutect2, varscan2
- LRRC37B | c.1989C>T p.R663= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV58951730; called by muse, mutect2
- LRRC4 | c.198C>G p.L66= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV50818238; called by muse, mutect2, varscan2
- MAN2B2 | c.2826G>A p.Q942= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV53456701; called by muse, mutect2, varscan2
- MDC1 | c.2886C>A p.A962= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV64523353, COSV64527500; called by muse, mutect2, varscan2
- MED26 | c.226C>T p.L76= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV54662948; called by muse, mutect2, varscan2
- MICAL2 | c.4635C>A p.P1545= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV56288584; called by muse, mutect2, varscan2
- MOGAT3 | c.975G>A p.E325= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV56177026; called by muse, mutect2, varscan2
- MUC1 | c.3228G>A p.L1076= (on ENST00000611571 / NM_001371720.1; = p.L87= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV58118453; called by muse, mutect2, varscan2
- MUC4 | c.1647C>A p.S549= | Silent (SNP) | VAF 30/248 reads (12%) | catalogued as COSV62193166; called by muse, mutect2, varscan2
- NECTIN2 | c.189G>A p.L63= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52980097; called by muse, mutect2, varscan2
- NPR3 | c.393C>A p.I131= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV54092987; called by muse, mutect2, varscan2
- NPTN | c.141C>A p.A47= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV54739883; called by muse, mutect2, varscan2
- NRN1L | c.201G>A p.E67= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV59303852; called by muse, mutect2
- NTRK2 | c.246C>A p.I82= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV52881718; called by muse, mutect2, varscan2
- OLFM2 | c.1356G>T p.G452= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV53433434; called by mutect2, varscan2
- OR10G9 | c.759C>A p.P253= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV66686817; called by muse, mutect2, varscan2
- OR14J1 | c.126C>G p.L42= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV65845737, COSV65845971; called by muse, mutect2, varscan2
- OR51A7 | c.561G>A p.L187= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as COSV63788953; called by muse, mutect2
- PCNX4 | c.1068C>T p.C356= (on ENST00000406854 / NM_001330177.2; = p.C122= on NM_022495.5) | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs577510197, COSV58307987; called by muse, mutect2, varscan2
- PHC3 | c.36G>A p.V12= (on ENST00000494943 / NM_001308116.2; = p.V24= on NM_024947.4) | Silent (SNP) | VAF 41/279 reads (15%) | catalogued as COSV71923751; called by muse, mutect2, varscan2
- PI4KA | c.6291G>A p.Q2097= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV55412560; called by muse, mutect2, varscan2
- PIWIL3 | c.840C>G p.L280= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV59998081; called by muse, mutect2, varscan2
- PLK3 | c.1902C>A p.R634= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV59501161; called by muse, mutect2
- PPP1R12B | c.1740C>G p.L580= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV61117541, COSV61123582; called by muse, mutect2
- PPP1R15A | c.891C>A p.P297= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV52340275; called by muse, mutect2, varscan2
- PRSS1 | c.411G>A p.T137= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs369013081, COSV61190980; called by muse, mutect2, varscan2
- PRX | c.3972G>A p.E1324= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99396976; called by muse, mutect2
- PTPRN2 | c.2556C>T p.G852= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV66104976; called by muse, mutect2, varscan2
- PWWP2A | c.834C>T p.I278= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as COSV61047998; called by muse, mutect2, varscan2
- RECQL4 | c.3147C>T p.D1049= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs767781957, COSV100020794; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPA4 | c.435T>C p.I145= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV61291365; called by muse, mutect2, varscan2
- RREB1 | c.2298T>C p.R766= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100619756; called by muse, mutect2
- SBF2 | c.2661G>A p.E887= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs1247451463, COSV56311087; called by muse, mutect2, varscan2
- SEC14L2 | c.372G>A p.K124= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV57242620; called by muse, mutect2, varscan2
- SERINC3 | c.432C>T p.I144= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs371830867; called by muse, mutect2, varscan2
- SERPINA5 | c.999G>A p.L333= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV61575039; called by muse, mutect2, varscan2
- SKIV2L | c.795G>A p.A265= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs759333847, COSV64810271; called by muse, mutect2, varscan2
- SLC16A7 | c.1254C>T p.S418= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs952553480, COSV99676796; called by muse, mutect2
- SLC18A3 | c.1518C>T p.G506= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV60332684; called by muse, mutect2
- SLC24A3 | c.1365G>A p.P455= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV60131872; called by muse, mutect2, varscan2
- SLC27A2 | c.618C>A p.I206= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV51062590; called by muse, mutect2, varscan2
- SLC5A10 | c.339C>T p.I113= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV58761923; called by muse, mutect2, varscan2
- SMCHD1 | c.4542C>A p.V1514= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV55267932; called by muse, mutect2, varscan2
- SOX9 | c.711A>G p.P237= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV55428392; called by muse, mutect2, varscan2
- STAT5A | c.2031G>A p.E677= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV61808379; called by muse, mutect2
- TARBP1 | c.2808C>T p.L936= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV50205136; called by muse, mutect2, varscan2
- TES | c.1020C>T p.Y340= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs770830785, COSV64042832; called by muse, mutect2, varscan2
- TMEM252 | c.201T>C p.T67= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV101051107, COSV66065913; called by muse, mutect2, varscan2
- TMEM39A | c.247C>T p.L83= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs201705221, COSV59900084, COSV59901487; called by muse, mutect2, varscan2
- TP53 | c.363T>A p.S121= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV53584943; called by muse, mutect2, varscan2
- TRIM4 | c.1122T>C p.V374= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV62470348; called by muse, mutect2, varscan2
- TTLL11 | c.1458G>A p.T486= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs199532582, COSV58652912; called by muse, mutect2, varscan2
- UPF1 | c.2088C>T p.F696= (on ENST00000599848 / NM_001297549.2; = p.F685= on NM_002911.4) | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs149225517; called by muse, mutect2, varscan2
- UVSSA | c.2109G>A p.Q703= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs757116685, COSV66230905; called by muse, mutect2, varscan2
- VPREB3 | c.291C>A p.A97= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV50707631; called by muse, mutect2, varscan2
- YLPM1 | c.288C>A p.G96= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- ZBTB20 | c.318A>G p.V106= (on ENST00000474710 / NM_001164342.2; = p.V33= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV61853860; called by muse, mutect2
- ZNF280D | c.2532C>T p.H844= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs779584219, COSV51000543; called by muse, mutect2, varscan2
- ZNF324 | c.561G>A p.R187= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99543446; called by muse, mutect2
- ZNF335 | c.1530C>G p.L510= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV59820119; called by muse, mutect2, varscan2
- ZNF536 | c.1860G>A p.L620= | Silent (SNP) | VAF 27/171 reads (16%) | catalogued as rs1207199096, COSV62833725; called by muse, mutect2, varscan2
- AGAP7P | n.1421C>T | RNA (SNP) | VAF 7/212 reads (3%) | catalogued as rs782743346; called by muse, mutect2
- C9orf106 | n.477G>C | RNA (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- CACNA1G | c.4422+46G>T | Intron (SNP) | VAF 12/54 reads (22%) | catalogued as COSV61738858; called by muse, mutect2, varscan2
- CTSL3P | n.496C>T | RNA (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2
- FSD2 | c.*3282T>C | 3'UTR (SNP) | VAF 13/145 reads (9%) | catalogued as COSV100575262; called by muse, mutect2
- HERC2P3 | n.889C>A | RNA (SNP) | VAF 16/180 reads (9%) | called by muse, varscan2
- HSD11B1L | c.669-94G>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs1275236052, COSV100028683; called by muse, mutect2
- MORF4 | n.282G>T | RNA (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2, varscan2
- PIGQ | c.*2G>A | 3'UTR (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99216427; called by muse, mutect2, varscan2
- SACS | c.*692G>A | 3'UTR (SNP) | VAF 5/29 reads (17%) | catalogued as rs759926296, COSV54568963; called by muse, mutect2
- SLCO2A1 | chr3:133928390 G>C | 3'Flank (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100189254, COSV60489656; called by muse, mutect2
- SMC4 | c.687+244C>A | Intron (SNP) | VAF 10/122 reads (8%) | catalogued as COSV100644113; called by muse, mutect2
- SWI5 | c.-74C>T | 5'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as COSV60793103; called by muse, mutect2, varscan2
- SYT1 | c.929-24760C>T | Intron (SNP) | VAF 13/67 reads (19%) | catalogued as rs758584383, COSV99696746; called by muse, mutect2, varscan2
- TTN | c.10303+2620G>A | Intron (SNP) | VAF 14/64 reads (22%) | catalogued as COSV60335350; called by muse, mutect2, varscan2
- UCHL5 | chr1:193059961 C>T | 5'Flank (SNP) | VAF 6/38 reads (16%) | catalogued as rs772044717, COSV66477912; called by muse, mutect2, varscan2
- WNK1 | c.2140-2397G>T | Intron (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100268290; called by muse, mutect2, varscan2
